Gene-level copy-number profile of tumor specimen TCGA-IA-A40Y-01A from TCGA case TCGA-IA-A40Y, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 60.2 years (21,996 days).
Specimen TCGA-IA-A40Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.661cc45f-8d26-4b57-a570-eadcf002806a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IA-A40Y-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5f46bda0-7cff-4bab-beaa-42a4353b5fc7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,597; copy number 2: 21,740; copy number 3: 11,721; copy number 4: 18,570; copy number 5: 5,969; copy number 7: 223.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IA-A40Y-01A-11D-A253-01): tumor purity 0.78, ploidy 3.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,192 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,399,560–248,919,946, 2,291 genes, copy number 5 (broad region; genes not listed).
- chr2:38,814–56,386,172, 920 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–29,600,868, 446 genes, copy number 5 (broad region; genes not listed).
- chr12:66,767–48,982,620, 1,077 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,389. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
